Somatic mutation profile of tumor specimen TCGA-FG-A6J1-01A (aliquot TCGA-FG-A6J1-01A-11D-A31L-08) from TCGA case TCGA-FG-A6J1, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 44.1 years (16,106 days).
Specimen TCGA-FG-A6J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08984518-44d8-4a30-a7b6-04fd4be64884.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A6J1-10A (Blood Derived Normal), aliquot TCGA-FG-A6J1-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64c5363e-c3cc-40ac-80ab-21ee93acc9fa

The open-access MAF lists 29 somatic variants for this specimen: 16 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 14, Silent 13, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/87 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACACA | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs769240769; called by muse, mutect2, varscan2
- CBLB | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99913500; called by muse, mutect2, varscan2
- CIC | c.3347dup p.S1117Kfs*34 | Frame Shift Ins (INS) | VAF 47/81 reads (58%) | catalogued as rs761345552; called by mutect2, varscan2
- EBF3 | c.1489G>A p.A497T (on ENST00000355311 / NM_001375392.1; = p.A488T on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.047); catalogued as rs138447716, COSV100799028; called by muse, mutect2
- FOLH1 | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99922862, COSV99923244; called by muse, varscan2
- MYOC | c.1413T>A p.Y471* | Nonsense Mutation (SNP) | VAF 27/145 reads (19%) | catalogued as COSV99231520; called by muse, mutect2, varscan2
- OR1D5 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101643426; called by muse, mutect2, varscan2
- OTOL1 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996665806, COSV60006035; called by muse, mutect2
- POF1B | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.023); catalogued as COSV99426753; called by muse, mutect2, varscan2
- RYR2 | c.9244C>T p.H3082Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV100770408, COSV63659423, COSV63719949; called by muse, varscan2
- U2SURP | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.292); catalogued as rs761426654, COSV101204491; called by muse, mutect2, varscan2
- UPK3B | c.535G>A p.G179R (on ENST00000257632; = p.G124R on NM_001347684.2) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.692); catalogued as rs756814597, COSV99991087; called by muse, varscan2
- USP11 | c.2785C>T p.R929C (on ENST00000218348; = p.R886C on NM_001371072.1) | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760876517, COSV54474099; called by muse, mutect2, varscan2
- ZBTB20 | c.1801A>G p.T601A (on ENST00000474710 / NM_001164342.2; = p.T528A on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100613938; called by muse, mutect2
- ZNF662 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV100066370; called by muse, mutect2
- CLIP1 | c.882C>T p.N294= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs111985493, COSV56807426; called by muse, mutect2, varscan2
- DUOX1 | c.2832T>C p.P944= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV100368015; called by muse, mutect2
- ELAVL1 | c.381T>C p.S127= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs549532291, COSV100688373; called by muse, mutect2, varscan2
- FBXO15 | c.1293G>A p.L431= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as COSV99503361; called by muse, mutect2
- KIF1B | c.2865C>G p.L955= (on ENST00000377086 / NM_001365952.1; = p.L909= on NM_015074.3) | Silent (SNP) | VAF 58/73 reads (79%) | catalogued as rs771415270, COSV55806497; called by muse, mutect2, varscan2
- KRT25 | c.1017G>A p.A339= | Silent (SNP) | VAF 28/307 reads (9%) | catalogued as rs753281617, COSV56443647; called by muse, mutect2
- MEF2B | c.150C>T p.S50= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs748789152, COSV99364713; called by muse, mutect2, varscan2
- MORC2 | c.2670A>G p.E890= (on ENST00000397641 / NM_001303256.3; = p.E828= on NM_014941.3) | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV99309904; called by muse, mutect2, varscan2
- NBR1 | c.2325A>G p.E775= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100357846; called by muse, mutect2, varscan2
- NUP205 | c.1386A>G p.E462= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as COSV99607043; called by muse, mutect2
- OR4A16 | c.741C>T p.L247= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs1346457574, COSV100125249, COSV59043426, COSV59045211; called by muse, mutect2, varscan2
- PURB | c.606C>T p.G202= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs947124778, COSV67480484; called by muse, mutect2, varscan2
- TRRAP | c.5280C>T p.N1760= (on ENST00000359863 / NM_001244580.1; = p.N1742= on NM_003496.3) | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as rs113411331, COSV100722511; called by muse, mutect2, varscan2
